Somatic mutation profile of tumor specimen MMRF_2076_1_BM_CD138pos (aliquot MMRF_2076_1_BM_CD138pos_T1_KHS5U_L08128) from MMRF case MMRF_2076, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 72.1 years (26,338 days).
Specimen MMRF_2076_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 42b95a50-713f-4b9f-a053-1c504bc61c33.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2076_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2076_1_PB_Whole_C2_KHS5U_L08129; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/24fa3de1-cf17-41ce-877b-92f54648fa32

The open-access MAF lists 226 somatic variants for this specimen: 102 protein-altering or splice-affecting, 24 silent, 100 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 80, 3'UTR 44, Intron 29, Silent 24, 5'UTR 17, Nonsense Mutation 8, Frame Shift Del 6, RNA 5, Splice Region 4, In Frame Del 3, 5'Flank 3, 3'Flank 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIM1 | c.72G>C p.K24N | Missense Mutation (SNP) | VAF 31/56 reads (55%) | hotspot (GDC flag); SIFT tolerated (0.48); PolyPhen benign (0.062); catalogued as COSV65164988, COSV65166078, COSV65166386; called by muse, mutect2, varscan2
- ACE | c.772G>A p.V258I | Missense Mutation (SNP) | VAF 67/121 reads (55%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.481); catalogued as rs747960808, COSV52009403; called by muse, mutect2, varscan2
- ADAMTS9 | c.3139A>G p.R1047G | Missense Mutation (SNP) | VAF 49/87 reads (56%) | SIFT tolerated (0.26); PolyPhen benign (0.04); catalogued as COSV99900226; called by muse, mutect2, varscan2
- AMH | c.1103C>A p.S368* | Nonsense Mutation (SNP) | VAF 6/12 reads (50%) | catalogued as rs375971454; called by muse, varscan2
- BCLAF1 | c.38C>G p.S13* | Nonsense Mutation (SNP) | VAF 13/39 reads (33%) | catalogued as rs1402122246; called by muse, mutect2
- BHLHE41 | c.733G>A p.E245K | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV54378519, COSV54379410; called by muse, mutect2, varscan2
- CSMD1 | c.4892C>T p.T1631M (on ENST00000520002; = p.T1630M on NM_033225.6) | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as rs535734466, COSV59283469; called by muse, mutect2, varscan2
- DCLRE1C | c.708G>T p.R236S (on ENST00000378278 / NM_001350965.2; = p.R121S on NM_022487.4) | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as rs1389842497; called by muse, mutect2, varscan2
- DNAH10 | c.3255G>T p.K1085N (on ENST00000409039; = p.K1024N on NM_207437.3) | Missense Mutation (SNP) | VAF 59/135 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as rs1353585133; called by muse, mutect2, varscan2
- EGLN1 | c.606G>A p.M202I | Missense Mutation (SNP) | VAF 37/78 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.041); catalogued as CD080824, COSV64147751; called by muse, mutect2, varscan2
- FGD5 | c.1979C>T p.T660M | Missense Mutation (SNP) | VAF 32/89 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.951); catalogued as rs375231003; called by muse, mutect2, varscan2
- GDPD3 | c.708-6C>G | Splice Region (SNP) | VAF 21/43 reads (49%) | catalogued as rs374555890; called by muse, mutect2, varscan2
- GFOD1 | c.43C>G p.R15G | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.156); catalogued as rs148284020; called by muse, mutect2, varscan2
- GRIN3B | c.2107G>A p.E703K | Missense Mutation (SNP) | VAF 79/110 reads (72%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.786); catalogued as rs758691413; called by muse, mutect2, varscan2
- GSDMB | c.138C>A p.F46L | Missense Mutation (SNP) | VAF 53/104 reads (51%) | SIFT tolerated (0.15); PolyPhen benign (0.061); catalogued as rs760832062; called by muse, mutect2, varscan2
- HLA-C | c.388G>A p.D130N | Missense Mutation (SNP) | VAF 29/60 reads (48%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.038); catalogued as rs41544015; called by muse, mutect2, varscan2
- IGHV3-30 | c.61G>A p.V21M | Missense Mutation (SNP) | VAF 26/112 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.957); catalogued as rs772782203; called by muse, mutect2, varscan2
- IGKV1-5 | c.63A>T p.K21N | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs377188226; called by muse, varscan2
- IGLV3-1 | c.61T>C p.Y21H | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.358); catalogued as rs372924773; called by muse, varscan2
- KLHDC7A | c.529G>A p.D177N | Missense Mutation (SNP) | VAF 64/123 reads (52%) | SIFT tolerated (0.4); PolyPhen benign (0.027); catalogued as rs775606176, COSV68770316; called by muse, mutect2, varscan2
- MRPL15 | c.887C>T p.S296L | Missense Mutation (SNP) | VAF 33/57 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as rs201769943; called by muse, mutect2, varscan2
- MUC16 | c.42307G>A p.E14103K | Missense Mutation (SNP) | VAF 50/85 reads (59%) | SIFT tolerated, low confidence (0.33); PolyPhen probably damaging (0.961); catalogued as rs552173997, COSV101109401, COSV66694165; called by muse, mutect2, varscan2
- MYO16 | c.244G>A p.E82K | Missense Mutation (SNP) | VAF 66/68 reads (97%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.478); catalogued as COSV51814391; called by muse, mutect2, varscan2
- NCBP2AS2 | c.182C>G p.S61C | Missense Mutation (SNP) | VAF 25/40 reads (63%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs1560172889; called by muse, mutect2, varscan2
- NR5A2 | c.103G>T p.A35S | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.067); catalogued as rs1459751058; called by muse, mutect2, varscan2
- OR4C15 | c.85C>G p.L29V | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.15); catalogued as COSV58950958; called by muse, mutect2, varscan2
- PLOD2 | c.1640G>A p.R547H | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs376497013; called by muse, mutect2, varscan2
- PLXNA2 | c.3134G>A p.R1045H | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as rs561631648, COSV65442856; called by muse, mutect2, varscan2
- PRDM4 | c.1550A>G p.D517G | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.053); catalogued as COSV99946848; called by muse, mutect2, varscan2
- PROK2 | c.76del p.D26Tfs*4 | Frame Shift Del (DEL) | VAF 11/45 reads (24%) | catalogued as rs1226828513; called by mutect2, pindel, varscan2
- PTPRN2 | c.1621A>G p.S541G | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.216); catalogued as rs1263129142, COSV101235796; called by muse, mutect2
- QARS1 | c.1295+5G>A | Splice Region (SNP) | VAF 124/177 reads (70%) | catalogued as rs374561502; called by muse, mutect2, varscan2
- RCAN3 | c.610G>A p.E204K | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as COSV65558682; called by muse, mutect2, varscan2
- RCVRN | c.89C>T p.S30F | Missense Mutation (SNP) | VAF 38/84 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.027); catalogued as rs539811007; called by muse, mutect2, varscan2
- RECQL | c.1631_1633del p.K544del | In Frame Del (DEL) | VAF 46/106 reads (43%) | catalogued as rs749841294; called by pindel, varscan2
- SLC6A3 | c.1195G>A p.A399T | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.909); catalogued as rs761642181, COSV99548113; called by muse, mutect2, varscan2
- SPAG17 | c.4759G>A p.E1587K | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.797); catalogued as COSV60466680; called by muse, mutect2, varscan2
- STARD6 | c.472A>G p.M158V | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs1287704927; called by muse, mutect2, varscan2
- TBATA | c.286G>A p.G96R | Missense Mutation (SNP) | VAF 97/146 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs371780553; called by muse, mutect2, varscan2
- TLR8 | c.850C>T p.Q284* (on ENST00000218032 / NM_138636.5; = p.Q302* on NM_016610.4) | Nonsense Mutation (SNP) | VAF 68/112 reads (61%) | catalogued as COSV99486743; called by muse, mutect2, varscan2
- TMEM132A | c.796C>T p.R266W | Missense Mutation (SNP) | VAF 98/137 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs140281492; called by muse, mutect2, varscan2
- TTN | c.79301C>A p.S26434Y (on ENST00000591111; = p.S19010Y on NM_003319.4) | Missense Mutation (SNP) | VAF 24/47 reads (51%) | PolyPhen probably damaging (0.912); catalogued as COSV60349021; called by muse, mutect2, varscan2
- XAB2 | c.461G>A p.R154H | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.009); catalogued as rs527655130, COSV60697953; called by muse, mutect2, varscan2
- ZNF843 | c.176G>A p.R59Q | Missense Mutation (SNP) | VAF 18/32 reads (56%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.01); catalogued as rs936300255; called by muse, mutect2, varscan2
- ABHD1 | c.1177G>A p.D393N | Missense Mutation (SNP) | VAF 39/56 reads (70%) | SIFT tolerated (0.65); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ACSS1 | c.1950G>T p.K650N | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- AMOTL2 | c.931C>G p.L311V | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT tolerated (0.1); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- ANKRD17 | c.2174C>T p.S725L | Missense Mutation (SNP) | VAF 81/129 reads (63%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); called by muse, mutect2, varscan2
- ANKRD62 | c.1940C>G p.S647* | Nonsense Mutation (SNP) | VAF 79/118 reads (67%) | called by muse, mutect2, varscan2
- BEND3 | c.1384A>C p.M462L | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT tolerated (0.19); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CAPN8 | c.426G>T p.Q142H | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- CAPZB | c.808C>T p.Q270* | Nonsense Mutation (SNP) | VAF 30/57 reads (53%) | called by muse, mutect2, varscan2
- CCT7 | c.446+7C>T | Splice Region (SNP) | VAF 30/64 reads (47%) | called by muse, mutect2, varscan2
- CDHR3 | c.99G>C p.E33D | Missense Mutation (SNP) | VAF 19/25 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CHMP3 | c.421G>T p.E141* | Nonsense Mutation (SNP) | VAF 41/84 reads (49%) | called by muse, mutect2, varscan2
- CNTF | c.340C>T p.L114F | Missense Mutation (SNP) | VAF 70/109 reads (64%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- COL6A5 | c.872C>G p.S291* | Nonsense Mutation (SNP) | VAF 62/200 reads (31%) | called by muse, mutect2, varscan2
- CTSF | c.1106C>T p.S369L | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- DOCK10 | c.6030_6031insA p.Y2011Ifs*10 | Frame Shift Ins (INS) | VAF 36/78 reads (46%) | called by mutect2, varscan2
- FADS6 | c.421G>A p.A141T | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.46); called by muse, mutect2, varscan2
- GABRB3 | c.287G>A p.R96K | Missense Mutation (SNP) | VAF 116/177 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GGA2 | c.333C>G p.I111M | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GZMM | c.71_90del p.T24Rfs*105 | Frame Shift Del (DEL) | VAF 19/115 reads (17%) | called by mutect2, varscan2
- H3C12 | c.338_342del p.I113Sfs*9 | Frame Shift Del (DEL) | VAF 27/56 reads (48%) | called by mutect2, pindel, varscan2
- IL6 | c.23C>T p.A8V | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT tolerated (0.48); PolyPhen benign (0.409); called by muse, mutect2, varscan2
- KLC1 | c.841G>A p.A281T | Missense Mutation (SNP) | VAF 35/75 reads (47%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- LLGL2 | c.100C>A p.Q34K | Missense Mutation (SNP) | VAF 55/87 reads (63%) | SIFT tolerated (0.67); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- LOXHD1 | c.2620G>A p.E874K | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- MAB21L4 | c.584G>A p.R195K (on ENST00000388934 / NM_001085437.3; = p.R27K on NM_024861.4) | Missense Mutation (SNP) | VAF 48/109 reads (44%) | SIFT tolerated (0.79); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- MBD1 | c.1587_1599del p.V530Cfs*4 (on ENST00000269468 / NM_001323950.1; = p.V428Cfs*4 on NM_002384.2) | Frame Shift Del (DEL) | VAF 6/38 reads (16%) | called by mutect2, varscan2
- MCM3AP | c.2261T>C p.F754S | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- MCOLN1 | c.1130C>T p.A377V | Missense Mutation (SNP) | VAF 28/102 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- MLH3 | c.2609C>T p.S870F | Missense Mutation (SNP) | VAF 43/94 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.048); called by muse, varscan2
- NCOR2 | c.2944C>T p.H982Y | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.805); called by muse, mutect2, varscan2
- NKX6-1 | c.374C>T p.S125F | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PHRF1 | c.463A>T p.I155F | Missense Mutation (SNP) | VAF 34/95 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); called by muse, mutect2, varscan2
- PLEKHG1 | c.763T>C p.Y255H | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PLEKHM3 | c.599A>T p.Q200L | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- PLG | c.2198A>T p.E733V | Missense Mutation (SNP) | VAF 30/62 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.305); called by muse, mutect2, varscan2
- PNOC | c.206C>T p.S69F | Missense Mutation (SNP) | VAF 67/124 reads (54%) | SIFT deleterious (0); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- PPP2R5D | c.1143G>C p.L381F | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RPS9 | c.307G>C p.E103Q | Missense Mutation (SNP) | VAF 33/52 reads (63%) | SIFT tolerated (0.16); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- RTL5 | c.532G>A p.E178K | Missense Mutation (SNP) | VAF 104/172 reads (60%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- RYR3 | c.2497G>T p.G833C | Missense Mutation (SNP) | VAF 32/53 reads (60%) | SIFT tolerated (0.09); PolyPhen benign (0.437); called by muse, mutect2, varscan2
- SCN1A | c.743C>T p.S248L | Missense Mutation (SNP) | VAF 24/38 reads (63%) | SIFT deleterious (0); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- SCP2 | c.1118G>A p.R373K | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SERPINC1 | c.415A>G p.K139E | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT tolerated (0.19); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- SLC12A1 | c.578_580del p.G193del | In Frame Del (DEL) | VAF 60/223 reads (27%) | called by mutect2, pindel, varscan2
- SNX22 | c.392+7C>T | Splice Region (SNP) | VAF 37/58 reads (64%) | called by muse, mutect2, varscan2
- ST6GALNAC2 | c.816C>G p.F272L | Missense Mutation (SNP) | VAF 15/30 reads (50%) | PolyPhen benign (0.136); called by muse, varscan2
- TAF5 | c.1694G>A p.G565E | Missense Mutation (SNP) | VAF 33/48 reads (69%) | SIFT tolerated (0.06); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- THUMPD1 | c.670C>G p.L224V | Missense Mutation (SNP) | VAF 34/60 reads (57%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- TMC4 | c.494C>T p.S165F (on ENST00000617472 / NM_001145303.3; = p.S159F on NM_144686.4) | Missense Mutation (SNP) | VAF 28/40 reads (70%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.747); called by muse, mutect2, varscan2
- TMEM245 | c.1705C>T p.H569Y | Missense Mutation (SNP) | VAF 14/20 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); called by muse, varscan2
- TMPO | c.828_831del p.I278Hfs*10 | Frame Shift Del (DEL) | VAF 43/111 reads (39%) | called by mutect2, pindel, varscan2
- TTN | c.40044_40046del p.I13349del (on ENST00000591111; = p.I5925del on NM_003319.4) | In Frame Del (DEL) | VAF 26/58 reads (45%) | called by pindel, varscan2
- TUSC3 | c.403G>A p.E135K | Missense Mutation (SNP) | VAF 32/65 reads (49%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.734); called by muse, mutect2, varscan2
- XBP1 | c.240_241del p.N80Kfs*17 | Frame Shift Del (DEL) | VAF 24/52 reads (46%) | called by mutect2, varscan2
- YPEL5 | c.137A>G p.N46S | Missense Mutation (SNP) | VAF 101/183 reads (55%) | SIFT tolerated (0.16); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- ZMYM1 | c.2785A>T p.K929* | Nonsense Mutation (SNP) | VAF 6/16 reads (38%) | called by mutect2, varscan2
- ZNF431 | c.1459G>A p.E487K | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT tolerated (0.22); PolyPhen benign (0.26); called by muse, mutect2, varscan2
- ZNF777 | c.448G>C p.D150H | Missense Mutation (SNP) | VAF 62/100 reads (62%) | SIFT deleterious (0.01); PolyPhen benign (0.206); called by muse, varscan2
- AKAP17A | c.1980C>T p.S660= | Silent (SNP) | VAF 3/10 reads (30%) | catalogued as rs774500839; called by muse, mutect2
- ATP11A | c.3291C>T p.C1097= | Silent (SNP) | VAF 3/16 reads (19%) | called by muse, varscan2
- C16orf72 | c.192G>A p.Q64= | Silent (SNP) | VAF 37/68 reads (54%) | called by muse, mutect2, varscan2
- C6orf62 | c.606C>T p.I202= | Silent (SNP) | VAF 48/104 reads (46%) | called by muse, mutect2, varscan2
- CDKN2A | c.470G>A p.*157= | Silent (SNP) | VAF 31/89 reads (35%) | catalogued as COSV58721717; called by muse, mutect2, varscan2
- EPHA8 | c.771C>T p.I257= | Silent (SNP) | VAF 10/16 reads (63%) | catalogued as COSV51265959; called by muse, mutect2, varscan2
- FCRL1 | c.156C>T p.F52= | Silent (SNP) | VAF 31/63 reads (49%) | catalogued as COSV100839835; called by muse, mutect2, varscan2
- GRIA2 | c.1962C>T p.I654= | Silent (SNP) | VAF 16/58 reads (28%) | catalogued as rs972200439, COSV52385777; called by muse, mutect2, varscan2
- GTF3C4 | c.339C>T p.L113= | Silent (SNP) | VAF 18/68 reads (26%) | called by muse, varscan2
- HERC5 | c.45G>T p.S15= | Silent (SNP) | VAF 13/32 reads (41%) | catalogued as rs781587665; called by muse, mutect2, varscan2
- HGSNAT | c.1158C>T p.I386= | Silent (SNP) | VAF 35/76 reads (46%) | catalogued as COSV52817056; called by muse, mutect2, varscan2
- LRP12 | c.2190C>T p.L730= | Silent (SNP) | VAF 21/43 reads (49%) | called by muse, mutect2, varscan2
- MAGEA8 | c.18G>A p.K6= | Silent (SNP) | VAF 33/89 reads (37%) | catalogued as COSV99674444; called by muse, mutect2, varscan2
- MAN1A1 | c.1572C>T p.F524= | Silent (SNP) | VAF 18/55 reads (33%) | called by muse, mutect2, varscan2
- MICU1 | c.1359C>T p.F453= (on ENST00000361114 / NM_001195518.2; = p.F459= on NM_006077.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 12/32 reads (38%) | called by muse, mutect2, varscan2
- NCAPG | c.1413G>A p.A471= | Silent (SNP) | VAF 79/82 reads (96%) | catalogued as rs1394230437, COSV99265609; called by muse, mutect2, varscan2
- NLRP8 | c.1452C>T p.V484= | Silent (SNP) | VAF 88/130 reads (68%) | called by muse, mutect2, varscan2
- RETREG2 | c.321C>T p.L107= | Silent (SNP) | VAF 96/209 reads (46%) | called by muse, mutect2, varscan2
- SELE | c.1230C>T p.L410= | Silent (SNP) | VAF 24/57 reads (42%) | catalogued as COSV60977265, COSV60978418; called by muse, mutect2, varscan2
- SLC25A18 | c.87C>T p.I29= | Silent (SNP) | VAF 37/69 reads (54%) | catalogued as rs749744246, COSV59408725; called by muse, mutect2, varscan2
- SLC38A7 | c.1150C>T p.L384= | Silent (SNP) | VAF 64/105 reads (61%) | catalogued as COSV54704342; called by muse, mutect2, varscan2
- SNAPC3 | c.219G>A p.G73= | Silent (SNP) | VAF 8/18 reads (44%) | catalogued as rs750295441, COSV66459793; called by muse, mutect2, varscan2
- TAS2R16 | c.126G>A p.L42= | Silent (SNP) | VAF 79/123 reads (64%) | called by muse, mutect2, varscan2
- WFS1 | c.741T>C p.F247= | Silent (SNP) | VAF 10/11 reads (91%) | catalogued as CD153292; called by muse, mutect2, varscan2
- ABCB5 | c.*1274C>A | 3'UTR (SNP) | VAF 10/29 reads (34%) | called by muse, mutect2, varscan2
- AC008397.2 | c.*83C>T | 3'UTR (SNP) | VAF 4/9 reads (44%) | called by muse, mutect2
- ACAD8 | c.705+20G>A | Intron (SNP) | VAF 57/101 reads (56%) | called by muse, mutect2, varscan2
- ACBD6 | c.*132G>T | 3'UTR (SNP) | VAF 22/43 reads (51%) | called by muse, mutect2, varscan2
- ACBD7 | c.*618G>A | 3'UTR (SNP) | VAF 13/65 reads (20%) | called by muse, mutect2, varscan2
- ADCK1 | c.*26C>T | 3'UTR (SNP) | VAF 47/84 reads (56%) | called by muse, mutect2, varscan2
- AKIRIN2 | c.235+610C>T | Intron (SNP) | VAF 30/63 reads (48%) | called by muse, mutect2, varscan2
- AL163195.3 | c.-39+3038C>T | Intron (SNP) | VAF 11/15 reads (73%) | called by muse, mutect2, varscan2
- AP1G2 | c.-60G>A | 5'UTR (SNP) | VAF 13/25 reads (52%) | catalogued as rs979322732, COSV58113041; called by muse, mutect2, varscan2
- ARPP21 | c.261+1735G>A | Intron (SNP) | VAF 19/60 reads (32%) | called by muse, mutect2, varscan2
- ASIC3 | c.813+65C>T | Intron (SNP) | VAF 42/143 reads (29%) | called by muse, mutect2, varscan2
- BCAM | c.204+19G>C | Intron (SNP) | VAF 28/42 reads (67%) | called by muse, mutect2, varscan2
- C2orf91 | n.508G>A | RNA (SNP) | VAF 89/170 reads (52%) | catalogued as rs1223828267; called by muse, mutect2
- C3orf38 | c.*1181C>T | 3'UTR (SNP) | VAF 37/57 reads (65%) | catalogued as rs1418520646; called by muse, mutect2, varscan2
- C3orf70 | c.*4686C>G | 3'UTR (SNP) | VAF 28/41 reads (68%) | called by muse, mutect2, varscan2
- CASP8 | c.1-8177C>T | Intron (SNP) | VAF 31/51 reads (61%) | catalogued as rs776284223; called by muse, mutect2, varscan2
- CIB3 | c.-19C>T | 5'UTR (SNP) | VAF 64/193 reads (33%) | called by muse, mutect2, varscan2
- CKMT1A | c.*10G>A | 3'UTR (SNP) | VAF 18/480 reads (4%) | catalogued as rs1366751603; called by muse, mutect2
- CLDN23 | c.*121C>T | 3'UTR (SNP) | VAF 10/18 reads (56%) | called by muse, mutect2, varscan2
- CNTN3 | c.2705-159T>C | Intron (SNP) | VAF 9/16 reads (56%) | called by muse, mutect2, varscan2
- CPE | c.*179A>G | 3'UTR (SNP) | VAF 9/27 reads (33%) | called by muse, mutect2, varscan2
- CREM | c.891-382G>A | Intron (SNP) | VAF 25/40 reads (63%) | catalogued as COSV59768794; called by muse, mutect2, varscan2
- CST5 | c.-61C>T | 5'UTR (SNP) | VAF 29/53 reads (55%) | called by muse, mutect2, varscan2
- CTDSPL | c.*641G>C | 3'UTR (SNP) | VAF 25/33 reads (76%) | called by muse, mutect2, varscan2
- DCHS2 | n.6972G>A | RNA (SNP) | VAF 52/165 reads (32%) | called by muse, mutect2, varscan2
- DMKN | c.1038+1592A>G | Intron (SNP) | VAF 50/160 reads (31%) | called by muse, mutect2, varscan2
- DMRT2 | c.*239C>T | 3'UTR (SNP) | VAF 48/79 reads (61%) | called by muse, mutect2, varscan2
- DYNLT1 | c.193+268C>T | Intron (SNP) | VAF 8/25 reads (32%) | called by muse, mutect2, varscan2
- ECI2 | c.675-382G>T | Intron (SNP) | VAF 19/39 reads (49%) | called by muse, mutect2, varscan2
- EMC9 | c.-104C>T | 5'UTR (SNP) | VAF 26/54 reads (48%) | called by muse, mutect2, varscan2
- EOMES | c.*439G>A | 3'UTR (SNP) | VAF 8/24 reads (33%) | called by muse, mutect2, varscan2
- EPDR1 | c.*1518_*1521del | 3'UTR (DEL) | VAF 8/28 reads (29%) | catalogued as rs1215595464; called by pindel, varscan2
- ERP44 | c.-137C>T | 5'UTR (SNP) | VAF 58/180 reads (32%) | catalogued as rs893054704; called by muse, mutect2, varscan2
- ETS2 | c.*262G>A | 3'UTR (SNP) | VAF 16/46 reads (35%) | catalogued as rs564973656; called by muse, mutect2, varscan2
- FAM50A | c.*41C>T | 3'UTR (SNP) | VAF 18/35 reads (51%) | called by muse, varscan2
- FAM50A | c.*123C>T | 3'UTR (SNP) | VAF 4/9 reads (44%) | called by muse, varscan2
- GALNTL6 | c.138+655T>C | Intron (SNP) | VAF 32/46 reads (70%) | called by muse, mutect2, varscan2
- GRIN2A | c.*3294C>A | 3'UTR (SNP) | VAF 12/30 reads (40%) | called by muse, mutect2, varscan2
- HECW2 | c.*1846A>C | 3'UTR (SNP) | VAF 14/30 reads (47%) | called by muse, mutect2, varscan2
- HYAL3 | c.-116C>T | 5'UTR (SNP) | VAF 18/50 reads (36%) | called by muse, mutect2, varscan2
- IDS | c.-67G>A | 5'UTR (SNP) | VAF 32/107 reads (30%) | called by muse, mutect2, varscan2
- IGHJ6 | chr14:105863430 del C | 5'Flank (DEL) | VAF 7/11 reads (64%) | called by mutect2, varscan2
- IKZF1 | c.*1544T>G | 3'UTR (SNP) | VAF 18/58 reads (31%) | called by muse, mutect2, varscan2
- IRF4 | c.*3632C>T | 3'UTR (SNP) | VAF 43/69 reads (62%) | called by muse, mutect2, varscan2
- ISG20L2 | c.-744G>A | 5'UTR (SNP) | VAF 17/47 reads (36%) | called by muse, mutect2, varscan2
- ITPR3 | c.-252A>C | 5'UTR (SNP) | VAF 8/9 reads (89%) | called by muse, mutect2, varscan2
- KBTBD11 | c.-885G>A | 5'UTR (SNP) | VAF 10/21 reads (48%) | called by muse, mutect2, varscan2
- KDM3B | c.*299T>A | 3'UTR (SNP) | VAF 28/79 reads (35%) | called by muse, mutect2, varscan2
- KLF7 | c.-217C>T | 5'UTR (SNP) | VAF 22/41 reads (54%) | called by muse, mutect2, varscan2
- KLF9 | c.-749A>C | 5'UTR (SNP) | VAF 45/135 reads (33%) | called by muse, mutect2, varscan2
- KLHL21 | c.1500+191G>A | Intron (SNP) | VAF 28/49 reads (57%) | called by muse, mutect2, varscan2
- KRT79 | c.*107C>T | 3'UTR (SNP) | VAF 21/36 reads (58%) | called by muse, mutect2, varscan2
- LRP2BP | c.*1461A>C | 3'UTR (SNP) | VAF 8/34 reads (24%) | called by muse, mutect2
- LYVE1 | c.*940T>A | 3'UTR (SNP) | VAF 4/56 reads (7%) | called by muse, mutect2
- MACIR | c.*301G>A | 3'UTR (SNP) | VAF 23/39 reads (59%) | called by muse, mutect2, varscan2
- MMP15 | c.-396C>T | 5'UTR (SNP) | VAF 5/9 reads (56%) | called by muse, mutect2, varscan2
- MON2 | c.*885_*888del | 3'UTR (DEL) | VAF 10/26 reads (38%) | called by pindel, varscan2
- MTARC1 | c.*772T>C | 3'UTR (SNP) | VAF 19/46 reads (41%) | called by muse, mutect2, varscan2
- MZB1 | c.177+46C>T | Intron (SNP) | VAF 28/36 reads (78%) | called by muse, mutect2, varscan2
- NANP | c.*1520G>T | 3'UTR (SNP) | VAF 35/66 reads (53%) | called by muse, mutect2, varscan2
- NF1 | c.1641+57A>G | Intron (SNP) | VAF 17/38 reads (45%) | called by muse, mutect2
- PALLD | c.1965-13101C>T | Intron (SNP) | VAF 24/41 reads (59%) | catalogued as rs1322635098; called by muse, mutect2, varscan2
- PDE2A | c.72-89G>A | Intron (SNP) | VAF 45/67 reads (67%) | called by muse, mutect2, varscan2
- PEDS1-UBE2V1 | c.*909C>T | 3'UTR (SNP) | VAF 40/94 reads (43%) | catalogued as rs1392791136; called by muse, mutect2, varscan2
- PELI1 | c.*1990A>G | 3'UTR (SNP) | VAF 11/24 reads (46%) | catalogued as rs1047458303; called by muse, mutect2, varscan2
- PHF20 | c.*1686G>A | 3'UTR (SNP) | VAF 17/34 reads (50%) | called by muse, mutect2, varscan2
- PHF8 | c.2757+1376C>T | Intron (SNP) | VAF 15/39 reads (38%) | called by muse, mutect2, varscan2
- PMP2 | c.*422G>A | 3'UTR (SNP) | VAF 29/63 reads (46%) | called by muse, mutect2, varscan2
- POLRMTP1 | n.2416C>T | RNA (SNP) | VAF 7/11 reads (64%) | called by muse, mutect2, varscan2
- PPATP1 | n.1454C>A | RNA (SNP) | VAF 41/148 reads (28%) | called by muse, mutect2, varscan2
- PRAME | chr22:22563672 G>C | 5'Flank (SNP) | VAF 26/51 reads (51%) | catalogued as rs1314841975; called by muse, mutect2, varscan2
- PXN | c.14-1907C>T | Intron (SNP) | VAF 28/50 reads (56%) | called by muse, mutect2, varscan2
- RAB33B | chr4:139453912 C>T | 5'Flank (SNP) | VAF 6/21 reads (29%) | called by muse, mutect2, varscan2
- RNF152 | c.*156G>T | 3'UTR (SNP) | VAF 42/66 reads (64%) | called by muse, mutect2, varscan2
- ROR1 | c.-277C>G | 5'UTR (SNP) | VAF 9/20 reads (45%) | called by muse, mutect2, varscan2
- RPAIN | c.-197C>T | 5'UTR (SNP) | VAF 15/30 reads (50%) | called by muse, mutect2, varscan2
- RPL35A | chr3:197956069 C>T | 3'Flank (SNP) | VAF 4/14 reads (29%) | catalogued as rs541919264; called by muse, mutect2, varscan2
- SAMSN1 | c.465+1845G>C | Intron (SNP) | VAF 9/47 reads (19%) | called by muse, mutect2, varscan2
- SELENOK | c.*26C>A | 3'UTR (SNP) | VAF 25/139 reads (18%) | catalogued as rs778750581; called by muse, mutect2, varscan2
- SIVA1 | c.470+573G>A | Intron (SNP) | VAF 48/106 reads (45%) | called by muse, mutect2, varscan2
- SLC39A14 | chr8:22421131 C>T | 3'Flank (SNP) | VAF 13/33 reads (39%) | called by muse, mutect2, varscan2
- SLC44A1 | c.*379T>C | 3'UTR (SNP) | VAF 22/33 reads (67%) | called by muse, mutect2, varscan2
- SMIM13 | c.*385+57G>A | Intron (SNP) | VAF 10/32 reads (31%) | catalogued as rs981479851; called by muse, mutect2, varscan2
- SORT1 | c.*4249G>C | 3'UTR (SNP) | VAF 22/44 reads (50%) | called by muse, mutect2, varscan2
- SP1 | c.-100C>T | 5'UTR (SNP) | VAF 8/25 reads (32%) | catalogued as rs937218905; called by mutect2, varscan2
- SRL | c.62-2107T>C | Intron (SNP) | VAF 23/57 reads (40%) | catalogued as rs1229594637; called by muse, mutect2, varscan2
- SRP14 | c.98-106G>A | Intron (SNP) | VAF 17/45 reads (38%) | called by muse, mutect2, varscan2
- TMEM187 | c.-12C>T | 5'UTR (SNP) | VAF 12/42 reads (29%) | catalogued as rs1213851528; called by muse, mutect2
- TMEM230 | c.*122C>A | 3'UTR (SNP) | VAF 39/100 reads (39%) | called by muse, mutect2, varscan2
- TMEM75 | n.1129C>G | RNA (SNP) | VAF 7/13 reads (54%) | called by muse, mutect2, varscan2
- TRPS1 | c.*703T>C | 3'UTR (SNP) | VAF 25/56 reads (45%) | called by muse, mutect2, varscan2
- TST | c.-21-214G>A | Intron (SNP) | VAF 37/91 reads (41%) | called by muse, mutect2, varscan2
- TXNDC5 | c.819+99G>A | Intron (SNP) | VAF 7/15 reads (47%) | called by muse, mutect2, varscan2
- TXNRD1 | c.*1822_*1823del | 3'UTR (DEL) | VAF 4/26 reads (15%) | catalogued as rs1491407299; called by pindel, varscan2
- UBA5 | c.161+182C>G | Intron (SNP) | VAF 97/136 reads (71%) | called by muse, mutect2, varscan2
- USP49 | c.*2031C>T | 3'UTR (SNP) | VAF 11/24 reads (46%) | called by muse, mutect2, varscan2
- ZBED6CL | c.*7C>T | 3'UTR (SNP) | VAF 205/341 reads (60%) | called by muse, mutect2, varscan2
- ZNF200 | c.*1406_*1411dup | 3'UTR (INS) | VAF 14/35 reads (40%) | called by mutect2, varscan2
- ZNF267 | c.3+1215del | Intron (DEL) | VAF 42/89 reads (47%) | called by mutect2, pindel, varscan2
- ZNF362 | c.*555G>A | 3'UTR (SNP) | VAF 18/36 reads (50%) | called by muse, mutect2, varscan2
